CCDI case PBBVIK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e35f2017-8ef7-48b8-b6fb-70d24fb11614

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,268 days).

Biospecimens (3 samples)
- Sample 0DI7SC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI7VB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DI7VG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
